Somatic mutation profile of tumor specimen TCGA-QK-A8Z9-01B (aliquot TCGA-QK-A8Z9-01B-11D-A391-08) from TCGA case TCGA-QK-A8Z9, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 56.0 years (20,471 days).
Specimen TCGA-QK-A8Z9-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7c2b2013-b20d-4857-a689-f3a83057fda3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A8Z9-10A (Blood Derived Normal), aliquot TCGA-QK-A8Z9-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1df8c9bc-5761-4860-a158-b1b623ecd13c

The open-access MAF lists 127 somatic variants for this specimen: 90 protein-altering or splice-affecting, 32 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 32, Nonsense Mutation 8, Frame Shift Del 3, Intron 3, Frame Shift Ins 2, 3'UTR 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>C p.R249S | Missense Mutation (SNP) | VAF 49/91 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC5 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99656756; called by muse, mutect2, varscan2
- ADAM22 | c.2054G>T p.G685V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as rs934208652, COSV99716541; called by muse, mutect2, varscan2
- AK5 | c.1428G>T p.R476S (on ENST00000354567 / NM_174858.3; = p.R450S on NM_012093.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV100642587; called by muse, mutect2, varscan2
- ANKRD6 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373880741; called by muse, mutect2, varscan2
- BOC | c.584A>T p.E195V | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as COSV99848567; called by muse, mutect2, varscan2
- BPHL | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100984469; called by muse, mutect2, varscan2
- BRINP1 | c.1427G>A p.S476N | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.932); catalogued as COSV99775198; called by muse, mutect2, varscan2
- CCDC62 | c.265C>T p.L89F | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99456928; called by muse, mutect2
- CD209 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs770034550, COSV52659254; called by muse, mutect2, varscan2
- CHML | c.1211A>T p.H404L | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100087298; called by muse, mutect2, varscan2
- CLSTN3 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as COSV99866875; called by muse, mutect2, varscan2
- CMYA5 | c.7999C>T p.P2667S | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.115); catalogued as COSV101484004, COSV101484449; called by muse, mutect2
- CUL3 | c.2106G>C p.E702D | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV52371601; called by muse, mutect2, varscan2
- DNM2 | c.2035A>G p.I679V (on ENST00000355667 / NM_001005360.3; = p.I675V on NM_004945.3) | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.163); catalogued as rs1381561772, COSV58961789; ClinVar: uncertain significance; called by muse, mutect2
- ETFDH | c.1419C>G p.I473M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100306794; called by muse, mutect2, varscan2
- FAM135B | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99422707, COSV99426362; called by muse, mutect2, varscan2
- FAM160B1 | c.1508A>G p.Y503C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs755554154, COSV100985409; called by muse, mutect2, varscan2
- FBXL7 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1239863082, COSV61640555; called by muse, mutect2, varscan2
- FMNL3 | c.2710G>A p.E904K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53302493; called by muse, mutect2, varscan2
- FNDC1 | c.2977C>A p.P993T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as COSV99795591; called by muse, mutect2
- FNDC3B | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.275); catalogued as COSV100394015; called by muse, mutect2, varscan2
- GIT2 | c.2223C>A p.D741E (on ENST00000355312 / NM_057169.5; = p.D663E on NM_014776.5) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV100618995; called by muse, mutect2, varscan2
- GPRC6A | c.158A>G p.D53G | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100114298; called by muse, mutect2, varscan2
- HCN1 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV100299847, COSV100300383, COSV57517027; called by muse, mutect2, varscan2
- HSPA13 | c.962C>G p.P321R | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99579983; called by muse, mutect2, varscan2
- INO80 | c.3199C>T p.Q1067* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100731765; called by muse, mutect2, varscan2
- IQCH | c.880G>C p.A294P | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100245689; called by muse, mutect2
- IRAK4 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.075); catalogued as COSV101471814; called by muse, mutect2, varscan2
- ISL1 | c.524A>T p.H175L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100045319; called by muse, mutect2, varscan2
- ITLN1 | c.671C>G p.S224* | Nonsense Mutation (SNP) | VAF 96/265 reads (36%) | catalogued as COSV100406197; called by muse, mutect2, varscan2
- KAZN | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101055390; called by muse, mutect2
- KCNMA1 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99696622; called by muse, mutect2, varscan2
- KCTD8 | c.1267A>G p.T423A | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.034); catalogued as COSV100759464; called by muse, mutect2, varscan2
- LINGO1 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.902); catalogued as rs1016098178, COSV100796365; called by muse, mutect2
- LMTK2 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99806660; called by muse, mutect2, varscan2
- LMTK3 | c.2764C>T p.P922S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV99540378; called by muse, mutect2, varscan2
- LRIT2 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.154); catalogued as rs1342597916, COSV100928301; called by muse, mutect2, varscan2
- LRRC4C | c.270C>G p.I90M | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV53426761, COSV99537890; called by muse, mutect2
- LRRCC1 | c.1501A>T p.K501* | Nonsense Mutation (SNP) | VAF 17/125 reads (14%) | catalogued as rs759370647, COSV64483107; called by muse, mutect2, varscan2
- MUC16 | c.35089A>G p.T11697A | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as rs937202903, COSV67450221; called by muse, mutect2, varscan2
- NADSYN1 | c.255C>G p.D85E | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100034675, COSV59810513; called by muse, mutect2
- NBEAL1 | c.7312A>G p.I2438V | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.985); catalogued as COSV101355466; called by muse, mutect2, varscan2
- NCAM1 | c.1033A>G p.T345A | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.253); catalogued as COSV100377545; called by muse, mutect2, varscan2
- NME8 | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52255492; called by muse, mutect2, varscan2
- NPY2R | c.370C>G p.H124D | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100279636; called by muse, mutect2, varscan2
- NUP58 | c.268A>T p.T90S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV101098693; called by muse, mutect2, varscan2
- OR5M8 | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 12/73 reads (16%) | catalogued as COSV100510641; called by muse, mutect2, varscan2
- PLCG1 | c.781T>C p.Y261H | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs758702634, COSV54817793; called by muse, mutect2, varscan2
- PXDC1 | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); catalogued as COSV100977196, COSV100977212; called by muse, mutect2, varscan2
- RANBP2 | c.3851G>A p.R1284K | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.017); catalogued as COSV99311918; called by muse, mutect2, varscan2
- RARA | c.975G>C p.E325D | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV99564845; called by muse, mutect2, varscan2
- RBCK1 | c.275A>G p.Y92C (on ENST00000356286 / NM_031229.4; = p.Y50C on NM_006462.6) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100675811; called by muse, mutect2, varscan2
- RNF115 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100991710; called by muse, mutect2, varscan2
- RNF139 | c.836A>G p.N279S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as rs1375550906, COSV99413333; called by muse, mutect2, varscan2
- RNF213 | c.9718C>T p.R3240W | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs753952938, COSV60395747; called by muse, mutect2, varscan2
- RTKN | c.272G>A p.R91Q (on ENST00000272430 / NM_001015055.2; = p.R78Q on NM_033046.2) | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs200885225, COSV51963643; called by muse, mutect2, varscan2
- SLC25A21 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 38/162 reads (23%) | catalogued as COSV100490997; called by muse, mutect2, varscan2
- SLFN5 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs139273106; called by muse, mutect2, varscan2
- SNW1 | c.533G>C p.R178P | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV99834313; called by muse, mutect2, varscan2
- SNX19 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV99772990; called by muse, mutect2, varscan2
- SPDEF | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.311); catalogued as COSV100927770; called by muse, mutect2, varscan2
- SPG11 | c.3661A>G p.I1221V | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99968455; called by muse, mutect2, varscan2
- SPHKAP | c.1589C>G p.P530R | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV100764061, COSV60875805; called by muse, mutect2, varscan2
- SYNE1 | c.24916G>A p.E8306K (on ENST00000367255 / NM_182961.4; = p.E8235K on NM_033071.3) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV99561301; called by muse, mutect2, varscan2
- TCP11 | c.694G>A p.E232K (on ENST00000512012; = p.E170K on NM_018679.5) | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.447); catalogued as COSV55136441, COSV99774255; called by muse, mutect2, varscan2
- THNSL1 | c.1198A>G p.R400G | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.043); catalogued as COSV100896174; called by muse, mutect2, varscan2
- TLR9 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.167); catalogued as rs746272802, COSV100645617; called by muse, mutect2, varscan2
- TMC7 | c.406C>T p.R136* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as rs1440222686, COSV100432440; called by muse, mutect2, varscan2
- TMEM151A | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1272100358, COSV59175097; called by muse, mutect2
- TPO | c.356T>C p.L119S | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV100220655; called by muse, mutect2, varscan2
- TRAV8-7 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.027); catalogued as rs776770640; called by muse, mutect2, varscan2
- TUT7 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.541); catalogued as COSV99462864; called by muse, mutect2, varscan2
- WDR41 | c.344T>C p.V115A | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV99689199; called by muse, mutect2, varscan2
- XIRP2 | c.1654G>T p.G552* (on ENST00000628543; = p.G727* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | catalogued as COSV99736640, COSV99741871; called by muse, mutect2, varscan2
- XPNPEP1 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs776040608, COSV100450957; called by muse, mutect2, varscan2
- ZNF142 | c.961G>A p.E321K (on ENST00000411696 / NM_001379660.1; = p.E121K on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV101376927; called by muse, mutect2, varscan2
- ZNF451 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773477753, COSV100674858; called by muse, mutect2, varscan2
- ZNF479 | c.850C>G p.L284V | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100482689; called by muse, mutect2, varscan2
- ZNF599 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100251098; called by muse, mutect2, varscan2
- ZNF675 | c.1466T>G p.F489C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100705019; called by muse, mutect2, varscan2
- ZNF750 | c.67T>C p.F23L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99489728; called by muse, mutect2, varscan2
- ZNF765 | c.238C>G p.H80D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV101125448; called by muse, mutect2, varscan2
- CIR1 | c.941_956del p.K314Mfs*21 | Frame Shift Del (DEL) | VAF 23/200 reads (12%) | called by mutect2, pindel
- IFT172 | c.4749_4752dup p.K1585Cfs*8 | Frame Shift Ins (INS) | VAF 8/94 reads (9%) | called by mutect2, pindel
- POLQ | c.6133_6149del p.R2045Hfs*25 | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel
- STX5 | c.994_999delinsGGT p.N332_R333delinsG | In Frame Del (DEL) | VAF 13/44 reads (30%) | called by pindel, varscan2*
- THAP10 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- WDR46 | c.786dup p.D263* | Frame Shift Ins (INS) | VAF 20/80 reads (25%) | called by mutect2, pindel, varscan2
- ZNF629 | c.2315del p.D772Vfs*65 | Frame Shift Del (DEL) | VAF 47/162 reads (29%) | called by mutect2, pindel, varscan2
- ADAM20 | c.1554T>C p.I518= | Silent (SNP) | VAF 29/135 reads (21%) | catalogued as COSV99833403; called by muse, mutect2, varscan2
- AHNAK | c.16818C>T p.L5606= | Silent (SNP) | VAF 67/193 reads (35%) | catalogued as COSV99947013; called by muse, mutect2, varscan2
- ALG5 | c.150A>G p.K50= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV99523609; called by muse, mutect2, varscan2
- ARID3B | c.1092C>T p.I364= | Silent (SNP) | VAF 25/128 reads (20%) | catalogued as COSV100654607; called by muse, mutect2, varscan2
- ATP13A4 | c.342G>A p.E114= | Silent (SNP) | VAF 35/131 reads (27%) | catalogued as rs1266862665, COSV99794399; called by muse, mutect2, varscan2
- CHRM3 | c.213C>T p.I71= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs199705116, COSV99698113; called by muse, mutect2, varscan2
- CUL2 | c.2235G>A p.A745= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs1008233441, COSV101038977; called by muse, mutect2, varscan2
- ERF | c.303G>T p.R101= | Silent (SNP) | VAF 50/201 reads (25%) | catalogued as COSV99724617; called by muse, mutect2, varscan2
- GGH | c.294A>T p.G98= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV99478826; called by muse, mutect2, varscan2
- ITGAD | c.9C>T p.F3= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as rs773502631, COSV66758158; called by muse, mutect2, varscan2
- IZUMO2 | c.258G>A p.A86= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs775383693, COSV99518231; called by muse, mutect2, varscan2
- KCNT2 | c.495A>T p.P165= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV54088151, COSV99653142; called by muse, mutect2, varscan2
- LIMK1 | c.1557G>A p.E519= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV100283127, COSV60281885; called by muse, mutect2, varscan2
- LRRK1 | c.2709C>T p.T903= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as rs370260141; called by muse, mutect2, varscan2
- MAP3K21 | c.2214C>T p.D738= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV100786096; called by muse, mutect2
- NOLC1 | c.1971A>G p.R657= | Silent (SNP) | VAF 44/220 reads (20%) | catalogued as COSV100893642; called by muse, mutect2, varscan2
- OTOGL | c.5787C>T p.C1929= (on ENST00000547103; = p.C1920= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as COSV100087151; called by muse, mutect2, varscan2
- PNLIPRP1 | c.453C>A p.L151= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100724348, COSV100724600; called by muse, mutect2, varscan2
- POM121 | c.960G>A p.E320= (on ENST00000434423; = p.E55= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/219 reads (16%) | catalogued as rs782654317, COSV99988137; called by muse, mutect2, varscan2
- RAB7A | c.285A>C p.T95= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as COSV99414029; called by muse, mutect2, varscan2
- RRP12 | c.957G>A p.P319= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs182185024; called by muse, mutect2, varscan2
- SCYL3 | c.1452C>T p.Y484= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs1368466899, COSV99609658; called by muse, mutect2, varscan2
- SMG1 | c.2277A>G p.K759= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1190194239, COSV101245727; called by muse, mutect2
- STK10 | c.1473C>T p.C491= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as COSV99451332; called by muse, mutect2, varscan2
- TLR10 | c.2130C>T p.F710= | Silent (SNP) | VAF 12/143 reads (8%) | catalogued as COSV100457578; called by muse, mutect2
- TMC6 | c.849C>T p.G283= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV100130042; called by muse, mutect2, varscan2
- TMEM179 | c.36C>T p.A12= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs1333695387, COSV100482027; called by muse, mutect2, varscan2
- TMEM61 | c.498C>T p.L166= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs1356736231, COSV100987736; called by muse, mutect2
- TRAV12-2 | c.27G>C p.V9= | Silent (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- UBAP2L | c.1053A>G p.E351= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV55169320, COSV99671029; called by muse, mutect2, varscan2
- USP3 | c.1324C>T p.L442= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV99165685; called by muse, mutect2, varscan2
- ZSWIM2 | c.402G>A p.G134= | Silent (SNP) | VAF 44/211 reads (21%) | catalogued as COSV99720120; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840434 G>C | 5'Flank (SNP) | VAF 10/154 reads (6%) | catalogued as COSV100006224, COSV58339775; called by muse, mutect2
- BTN2A3P | n.1448-371C>T | Intron (SNP) | VAF 48/145 reads (33%) | catalogued as rs746162420; called by muse, mutect2, varscan2
- CARS2 | c.1417-201del | Intron (DEL) | VAF 4/10 reads (40%) | called by mutect2, varscan2
- DPP6 | c.*380C>A | 3'UTR (SNP) | VAF 17/118 reads (14%) | catalogued as COSV100124869; called by muse, mutect2, varscan2
- PLCB4 | c.3460-2184A>T | Intron (SNP) | VAF 5/38 reads (13%) | catalogued as COSV53795240, COSV99595197; called by muse, mutect2, varscan2
